Gene-level copy-number profile of tumor specimen ALCH-ADIU-TTP1-A from ALCHEMIST case ALCH-ADIU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.5 years (22,111 days).
Specimen ALCH-ADIU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 526b6c85-2240-4d09-9e27-87b70f4b9548.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADIU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/38cc5de9-bd78-43c7-b64f-16da48aec816

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 3,773; copy number 2: 52,914; copy number 3: 1,464; copy number 4: 12; copy number 5: 62; copy number 6: 57; copy number 8: 8; copy number 10: 14; copy number 12: 9.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,018,875–16,073,651, 4 genes (within-gene range 0–2): CLCNKA, AL355994.2, CLCNKB, FAM131C.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:2,631,986–2,664,802, 1 gene: TTYH3.
- chr8:144,423,601–144,444,440, 4 genes (within-gene range 0–2): VPS28, TONSL, MIR6893, TONSL-AS1.
- chr11:64,340,204–64,357,534, 2 genes (within-gene range 0–2): CCDC88B, MIR7155.
- chr12:109,573,255–109,598,125, 1 gene (within-gene range 0–2): MVK.
- chr15:25,176,832–25,250,940, 41 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr17:2,366,589–2,366,791, 1 gene (within-gene range 0–1): AC006435.3.
- chr19:186,373–519,654, 16 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1.
- chr20:36,777,447–36,863,538, 1 gene: SOGA1.
- chr21:46,151,614–46,152,647, 1 gene (within-gene range 0–1): FTCD-AS1.
- chr22:35,336,721–35,336,799, 1 gene (within-gene range 0–2): MIR6069.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 149 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr20:34,280,268–34,560,345, 14 genes, copy number 5 (within-gene range 3–5): AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A.
- chr20:53,552,770–54,070,594, 8 genes, copy number 8 (within-gene range 1–8): AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1.
- chr20:57,488,392–59,113,631, 45 genes, copy number 5–12: HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2.
- chr20:62,513,909–63,129,459, 38 genes, copy number 6–10: AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2.
- chr20:63,520,765–63,936,031, 33 genes, copy number 6: PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5.
- chr21:10,482,738–13,016,692, 7 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Autosomal genes at a single copy (total copy number 1): 3,773. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
